Gene-level copy-number profile of tumor specimen TCGA-HN-A2OB-01A from TCGA case TCGA-HN-A2OB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 45.6 years (16,672 days).
Specimen TCGA-HN-A2OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b6a8307b-66fe-4aa1-aa5c-9cd0822c6d3f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HN-A2OB-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f141af63-e760-463e-8fdc-3ccea509d9ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,244; copy number 2: 54,488; copy number 3: 2,963; copy number 4: 74; copy number 5: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HN-A2OB-01A-21D-A27O-01): tumor purity 0.42, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,699,274–41,625,001, 51 genes, copy number 5 (within-gene range 3–5): AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4.

Autosomal genes at a single copy (total copy number 1): 2,244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
